Gene-level copy-number profile of tumor specimen HCM-BROD-0783-C71-02A from HCMI case HCM-BROD-0783-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 53.9 years (19,673 days).
Specimen HCM-BROD-0783-C71-02A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a012d1fd-2d68-40ef-bb81-bf8fe27a5f60.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0783-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,288 have no estimate.
https://portal.gdc.cancer.gov/files/4777949e-1c7d-4657-902b-d842e2bfc6b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 6,929; copy number 2: 43,951; copy number 3: 6,440; copy number 4: 906; copy number 5: 78; copy number 6: 18; copy number 7: 2; copy number 9: 1; copy number 20: 3; copy number 29: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:139,460,062–139,463,016, 1 gene: AC087354.1.
- chr14:106,703,846–106,762,588, 3 genes: IGHV1-68, IGHV2-70D, IGHV1-69D.
- chr19:42,949,503–42,950,387, 1 gene (within-gene range 0–1): CEACAMP7.
- chr22:35,066,136–35,087,387, 1 gene: ISX.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 97 genes in 42 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,908,152–11,908,271, 1 gene, copy number 5: RNU5E-1.
- chr1:28,329,002–28,335,965, 1 gene, copy number 5: MED18.
- chr1:28,589,323–28,643,085, 1 gene, copy number 5 (within-gene range 4–5): TAF12.
- chr1:28,643,228–28,719,353, 5 genes, copy number 5: LINC01715, AL360012.1, RNU11, GMEB1, AL645729.1.
- chr1:36,224,432–36,305,357, 2 genes, copy number 5: THRAP3, UBE2V2P4.
- chr1:156,192,063–156,212,796, 2 genes, copy number 5: AL135927.1, SLC25A44.
- chr3:48,094,801–48,095,105, 1 gene, copy number 6: RN7SL664P.
- chr3:138,652,698–138,834,928, 4 genes, copy number 5: PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25.
- chr4:40,020,240–40,021,517, 1 gene, copy number 5: KRT18P25.
- chr6:5,817,421–5,818,366, 1 gene, copy number 5: AL136968.1.
- chr6:37,170,152–37,175,428, 1 gene, copy number 5: PIM1.
- chr7:1,459,937–1,509,427, 4 genes, copy number 5: AC102953.1, AC102953.2, INTS1, AC093734.1.
- chr7:2,251,770–2,354,318, 1 gene, copy number 6 (within-gene range 3–6): SNX8.
- chr7:2,287,915–2,288,428, 1 gene, copy number 6: IMMP1LP3.
- chr7:5,103,719–5,144,546, 2 genes, copy number 6: OR10AH1P, ZNF890P.
- chr7:5,274,369–5,306,870, 1 gene, copy number 5 (within-gene range 4–5): SLC29A4.
- chr7:5,425,770–5,561,055, 8 genes, copy number 5–6: AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589, AC006483.2, AC006483.1.
- chr7:5,823,160–5,854,365, 1 gene, copy number 5: ZNF815P.
- chr7:5,925,550–6,093,085, 10 genes, copy number 6 (within-gene range 4–6): RSPH10B, PMS2, Y_RNA, AIMP2, SNORA80D, EIF2AK1, ANKRD61, RN7SL851P, RNU6-218P, AC004895.1.
- chr7:6,161,776–6,272,644, 2 genes, copy number 5: CYTH3, Y_RNA.
- chr7:72,947,581–73,005,922, 5 genes, copy number 5 (within-gene range 1–5): NSUN5P2, TRIM74, STAG3L3, AC211476.1, Y_RNA.
- chr7:73,220,624–73,280,119, 2 genes, copy number 5: NCF1B, GTF2IRD2P1.
- chr7:74,082,933–74,122,525, 1 gene, copy number 5: LIMK1.
- chr7:149,239,651–149,255,606, 1 gene, copy number 5: ZNF212.
- chr14:22,893,204–22,982,258, 7 genes, copy number 5 (within-gene range 4–5): RBM23, PRMT5-AS1, PRMT5, AL132780.1, HAUS4, AL132780.3, MIR4707.
- chr14:63,684,216–63,736,505, 3 genes, copy number 5: SGPP1, EIF2S2P1, RNU7-116P.
- chr14:63,762,013–63,762,149, 1 gene, copy number 5: AL161670.1.
- chr15:22,125,511–22,126,434, 1 gene, copy number 5 (within-gene range 3–5): OR4N3P.
- chr15:22,178,107–22,185,402, 2 genes, copy number 5: IGHV1OR15-3, IGHV4OR15-8.
- chr15:43,599,563–43,618,800, 1 gene, copy number 7 (within-gene range 3–7): STRC.
- chr15:43,614,208–43,632,283, 1 gene, copy number 7 (within-gene range 3–7): AC011330.3.
- chr15:84,467,901–84,502,381, 3 genes, copy number 20: Metazoa_SRP, UBE2Q2P12, AC048382.4.
- chr16:30,904,348–30,910,208, 1 gene, copy number 5: CTF2P.
- chr16:67,289,428–67,326,760, 2 genes, copy number 5 (within-gene range 3–5): KCTD19, RN7SKP118.
- chr16:67,549,214–67,639,177, 5 genes, copy number 5: AC027682.4, AC027682.7, AC027682.1, CTCF, AC009095.1.
- chr16:70,173,322–70,187,361, 1 gene, copy number 5: CLEC18C.
- chr17:42,609,683–42,676,994, 5 genes, copy number 5 (within-gene range 3–5): TUBG1, ATP5MGP7, HMGB3P27, TUBG2, PLEKHH3.
- chr17:59,209,400–59,215,247, 1 gene, copy number 5 (within-gene range 3–5): SMG8.
- chr20:36,870,099–36,870,402, 1 gene, copy number 5: RN7SL156P.
- chr21:43,092,956–43,107,570, 1 gene, copy number 29: U2AF1.

Autosomal genes at a single copy (total copy number 1): 6,900. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
